Gene-level copy-number profile of tumor specimen TCGA-K1-A6RV-01A from TCGA case TCGA-K1-A6RV, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 67.6 years (24,701 days).
Specimen TCGA-K1-A6RV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.779663ab-8330-4600-bebe-5477b5ce5fa7.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-K1-A6RV-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f01fa28e-b41d-4d0e-8785-433bf7763e3b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 78; copy number 1: 2,024; copy number 2: 23,136; copy number 3: 20,701; copy number 4: 10,885; copy number 5: 2,688; copy number 6: 199; copy number 7: 55; copy number 8: 10; copy number 9: 33.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-K1-A6RV-01A-11D-A32H-01): tumor purity 0.71, ploidy 2.93, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 74 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:14,309,033–14,332,663, 3 genes: EIF4EP5, RNU7-153P, Y_RNA.
- chr10:87,751,512–89,556,641, 44 genes: ATAD1, CFL1P1, RN7SL78P, KLLN, PTEN, AC063965.2, RPL11P3, AC063965.1, MED6P1, AL353149.1, RNLS, Y_RNA, LIPJ, RPL7P34, LIPF, NAPGP1, LIPK, KRT8P38, LIPN, RCBTB2P1, LIPM, ANKRD22, PTCD2P2, STAMBPL1, ACTA2-AS1, ACTA2, AL157394.3, FAS, AL157394.2, AL157394.1, MIR4679-2, MIR4679-1, AL513533.1, CH25H, LIPA, IFIT2, AL353751.1, IFIT3, IFIT6P, IFIT1B, IFIT1, IFIT5, SLC16A12, SLC16A12-AS1.
- chr15:98,646,951–98,964,530, 6 genes: IRAIN, IGF1R, AC118658.1, MIR4714, AC055807.1, AC069029.1.
- chr15:98,968,229–99,007,792, 1 gene (within-gene range 0–1): PGPEP1L.
- chr15:99,136,323–99,251,223, 1 gene (within-gene range 0–1): TTC23.
- chr15:99,251,362–99,716,466, 13 genes (within-gene range 0–1): LRRC28, HSP90B2P, HNRNPA1P62, AC037479.1, LINC02244, AC015660.2, AC015660.3, AC015660.1, AC015660.5, AC015660.4, RPL7P5, MEF2A, Y_RNA.
- chr15:99,805,793–100,342,005, 6 genes (within-gene range 0–2): AC090825.1, AC084855.1, ADAMTS17, AC084855.2, RNA5SP402, AC022710.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,951 genes in 41 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:78,170,481–78,540,701, 5 genes, copy number 5: RNFT1P2, MGC27382, PTGFR, AC096531.1, RNA5SP23.
- chr1:78,749,073–85,154,203, 70 genes, copy number 5–7 (broad region; genes not listed).
- chr1:118,614,333–121,580,524, 80 genes, copy number 5 (broad region; genes not listed).
- chr2:81,194,337–81,419,302, 2 genes, copy number 5: ANKRD11P1, CHMP4AP1.
- chr2:82,476,825–83,219,105, 9 genes, copy number 6: AC010105.1, RBX1P1, MTND4P25, MTND5P27, MTND6P7, MTCYBP7, AC098817.1, DHFRP3, AC138623.1.
- chr2:84,516,455–84,819,589, 3 genes, copy number 6 (within-gene range 4–6): DNAH6, DUXAP1, LDHAP7.
- chr2:142,131,178–142,543,975, 2 genes, copy number 5: AC078882.1, UBE2V1P14.
- chr2:143,093,056–143,172,172, 10 genes, copy number 5: MTCYBP11, MTND6P11, MTND5P24, MTND4P22, MTND4LP12, MTND3P9, MTCO3P5, MTATP6P5, MTCO2P5, AC013437.1.
- chr2:152,284,350–152,649,826, 5 genes, copy number 5 (within-gene range 2–5): Y_RNA, FMNL2, NUDCP1, AC012066.1, AC012443.1.
- chr2:153,158,938–154,453,979, 11 genes, copy number 5 (within-gene range 2–5): ATP5PBP4, AC011901.1, AC079150.1, LINC01850, RPL23AP29, TUBAP13, AC012501.2, AC012501.1, RPRM, DNAJA1P2, GALNT13.
- chr3:102,755,064–104,503,266, 8 genes, copy number 5: RNU6-461P, RNU1-43P, NDUFA4P2, MIR548AB, AC046144.1, TUBBP11, RAP1BP2, AC091804.1.
- chr3:114,103,249–114,310,288, 6 genes, copy number 5: H2BP3, DRD3, AC093010.1, FAM214BP1, ZNF80, TIGIT.
- chr3:114,314,501–114,529,452, 4 genes, copy number 5: AC093010.2, MIR568, ZBTB20-AS1, ZBTB20-AS5.
- chr3:117,544,205–120,094,994, 36 genes, copy number 5 (within-gene range 3–5): RNU6-1200P, AC092691.1, AC092691.2, LINC02024, AC092691.3, AC068633.1, AC068633.2, IGSF11, IGSF11-AS1, TEX55, AC083800.1, UPK1B, B4GALT4, B4GALT4-AS1, ARHGAP31, RPS26P21, ARHGAP31-AS1, RNU6-1127P, TMEM39A, POGLUT1, AC073352.1, TIMMDC1, CD80, AC073352.2, ADPRH, PLA1A, RPL10P7, POPDC2, COX17, AC023494.1, CFAP91, AC069444.2, AC069444.1, NR1I2, PHBP8, GSK3B.
- chr3:119,978,153–119,990,147, 1 gene, copy number 5: AC078856.1.
- chr3:123,968,521–123,992,178, 1 gene, copy number 5 (within-gene range 3–5): ROPN1.
- chr3:124,132,929–124,153,063, 2 genes, copy number 5: MIR5002, RPL7P15.
- chr4:2,462,220–2,625,320, 1 gene, copy number 5 (within-gene range 4–5): RNF4.
- chr4:2,505,081–36,913,339, 447 genes, copy number 5–9 (broad region; genes not listed).
- chr5:6,019,029–6,030,841, 2 genes, copy number 5: AC010266.2, AC010266.1.
- chr5:21,569,755–23,329,892, 14 genes, copy number 5: AC091946.2, AC091946.1, CDH12, HSPD1P1, AC139497.1, PMCHL1, AC138854.1, GCNT1P2, AC091938.1, AC010445.1, AC010460.2, Y_RNA, AC010460.3, AC010460.1.
- chr5:35,048,756–35,230,487, 1 gene, copy number 6 (within-gene range 4–6): PRLR.
- chr5:93,088,856–98,798,643, 93 genes, copy number 5 (broad region; genes not listed).
- chr8:124,192,671–144,428,563, 351 genes, copy number 5 (broad region; genes not listed).
- chr9:21,058,771–21,142,145, 5 genes, copy number 6: IFNNP1, IFNB1, IFNWP4, AL390882.1, IFNW1.
- chr10:111,322,778–111,498,941, 3 genes, copy number 5: BTBD7P2, AC021035.1, RPS6P15.
- chr11:41,394,595–41,426,504, 1 gene, copy number 5: AC090138.1.
- chr11:41,538,434–41,538,986, 1 gene, copy number 5: AC021006.1.
- chr11:44,260,440–44,736,692, 10 genes, copy number 5: ALX4, AC010768.4, AC010768.3, CD82, AC010768.1, AC010768.2, RPL34P22, AC104010.1, LINC02704, TSPAN18-AS1.
- chr11:54,591,480–63,144,221, 442 genes, copy number 5 (broad region; genes not listed).
- chr11:63,163,776–63,229,652, 1 gene, copy number 5 (within-gene range 3–5): SLC22A25.
- chr11:66,934,434–70,436,584, 136 genes, copy number 5 (broad region; genes not listed).
- chr11:70,477,277–70,477,592, 1 gene, copy number 5: AP001271.1.
- chr11:76,782,251–77,215,241, 9 genes, copy number 5 (within-gene range 3–5): TSKU, AP003119.2, AP003119.3, ACER3, AP002498.1, B3GNT6, CAPN5, OMP, MYO7A.
- chr13:67,326,177–85,148,121, 176 genes, copy number 5 (broad region; genes not listed).
- chr13:85,693,937–114,337,626, 399 genes, copy number 5 (broad region; genes not listed).
- chr17:142,789–2,381,058, 93 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr18:13,217,498–13,652,755, 1 gene, copy number 5 (within-gene range 4–5): LDLRAD4.
- chr18:13,362,203–15,330,282, 70 genes, copy number 5 (broad region; genes not listed).
- chr19:36,850,361–45,410,737, 438 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 739. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
